Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A6JT, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A6JT-01A (Primary Tumor).

[page 1 of 2]
M

(160.0cm 77.6kg BSA: 1.86m²

Accession:

Specimen Date/Time:

DIAGNOSIS

- (A) RIGHT LATERAL GLOSSECTOMY
INVASIVE SQUAMOUS CARCINOMA -- Moderately differentiated

Tumor Features:

Gross: Ulcerating
Size: 3 cm in largest dimension
Invasion: Present, depth 1.5 cm
Tumor Border: Infiltrative with thick cords > 4 cells
Perineural Invasion: Present, Focal
Vascular Invasion: Absent
Lymphocyte Infiltration: Absent

Mucosal Margin: (radial) Negative for invasive carcinoma
Deep Margin: (radial) Close < 2mm

- (B) RIGHT NECK CONTENTS, LEVEL I

Three lymph nodes, negative for tumor
Submandibular gland, negative for tumor

- (C) RIGHT NECK CONTENTS, LEVEL II

Five lymph nodes, negative for tumor

- (D) RIGHT NECK CONTENTS, LEVEL III

Twenty six lymph nodes, negative for tumor

- (E) DEEP TONGUE

Skeletal muscle, fibro-connective tissue and minor salivary gland, negative for tumor

GROSS DESCRIPTION

(A) RIGHT LATERAL GLOSSECTOMY, SINGLE STITCH ANTERIOR, DOUBLE STITCH SUPERIOR -- A 5 x 3 x 1.8 cm irregular tongue tissue. A light tan-white and firm nodule (2 x 1 x 3 cm) is on the cut surface. The tumor nodule abuts the deep margin. Serially sectioned from anterior to posterior and tissue entirely submitted in A1 -- A10.

(B) RIGHT NECK CONTENTS, LEVEL I -- One pale gray fibroadipose tissue (4.5 x 4.0 x 2.0 cm) including one pale gray, unremarkable submandibular gland (4.0 x 2.5 x 1.8 cm). Multiple possible lymph nodes are identified ranging from 0.3 x 0.3 x 0.3 cm to 1.5 x 0.9 x 0.7 cm. The lymph nodes are entirely submitted.

SECTION CODE: B1, B2, each contains four possible lymph nodes; B3, one possible lymph node serially sectioned; B4, representative section of the submandibular gland.

(C) RIGHT NECK CONTENTS, LEVEL II -- One pale gray fibroadipose tissue (4.5 x 3.0 x 1.0 cm) with six possible lymph nodes ranging from 0.4 x 0.3 x 0.3 cm to 0.9 x 0.8 x 0.7 cm. Lymph nodes entirely submitted.

SECTION CODE: C1, four possible lymph nodes; C2, C3, each contains one possible lymph node serially sectioned.

(D) RIGHT NECK CONTENTS, LEVEL III -- One pale gray fibroadipose tissue (4.5 x 3.2 x 1.5 cm) with multiple possible lymph

IRD-0-3

Carcinoma, squamous
cell NOS 0807013

Site Tongue NOS
002.9

9/8/9/13

[page 2 of 2]
M

(160.0cm 77.6kg BSA: 1.86m²)

Accession:

Specimen Date/Time:

nodes ranging from 0.2 x 0.2 x 0.2 cm – 0.7 x 0.5 x 0.4 cm. Lymph nodes entirely submitted.

SECTION CODE: D1-D6, each contain four possible lymph nodes; D7, three possible lymph nodes; D8, two possible lymph nodes.

(E) DEEP TONGUE, SINGLE LONG STITCH MARKS ANTERIOR, DOUBLE LONG STITCH MARKS SUPERIOR, INKED MARKS TRUE MARGIN – One pale gray vascular tissue (4.2 x 2.5 x 1.2 cm) with one side inked purple which marks true margin and a single long stitch marks anterior and double long stitch marks superior. The specimen is inked, serially sectioned and entirely submitted.

INK CODE: yellow – anterior, black – true margin, blue – superior.

SECTION CODE: E1-E6, entirely submitted specimen from anterior to posterior direction.

CLINICAL HISTORY

Right tongue lesion

SNOMED CODES

T-53000, M-80703, "Some tests reported here may have been developed and performance characteristics determined by tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

These

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file b8f7a213-5120-41ef-8574-60696b82c3fb (TCGA-CV-A6JT.D086126C-317A-4956-B516-288D8CDA118B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).